Somatic mutation profile of cancer-model specimen HCM-BROD-0045-C16-85A (3D Organoid, passage 8; aliquot HCM-BROD-0045-C16-85A-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0045-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 58.1 years (21,217 days).
Specimen HCM-BROD-0045-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf69723e-e074-4c6b-9415-817be017da57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0045-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0045-C16-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6834732-c2dc-46e9-9c8f-3ff8a7eee545

The open-access MAF lists 367 somatic variants for this specimen: 253 protein-altering or splice-affecting, 89 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 224, Silent 89, Nonsense Mutation 12, Intron 12, Splice Region 6, 3'UTR 6, Frame Shift Del 4, 5'Flank 4, Frame Shift Ins 4, RNA 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 163/163 reads (100%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 110/421 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as COSV68068547; called by muse, mutect2, varscan2
- ADAM11 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 117/303 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776624927; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 111/244 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs748416492; called by muse, mutect2, varscan2
- ANGPT2 | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs750598634; called by muse, mutect2, varscan2
- ANKRD40 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 85/462 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs778549569, COSV53333196; called by muse, mutect2, varscan2
- APOB | c.12578T>A p.L4193H | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV99028798; called by muse, mutect2, varscan2
- ATF6B | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 249/619 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372088619; called by muse, mutect2, varscan2
- AXIN1 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 258/258 reads (100%) | catalogued as COSV51982971; called by muse, mutect2, varscan2
- AXIN2 | c.1713C>T p.G571= | Splice Region (SNP) | VAF 112/477 reads (23%) | catalogued as rs761978806; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- C7orf26 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 270/402 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100732973; called by muse, mutect2, varscan2
- CBY2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 37/560 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs372471800; called by muse, mutect2
- CCDC136 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765936662; called by muse, mutect2, varscan2
- CCDC88C | c.5303C>T p.P1768L | Missense Mutation (SNP) | VAF 310/680 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs376412313; called by muse, mutect2, varscan2
- CCR2 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 218/315 reads (69%) | SIFT tolerated (0.41); PolyPhen benign (0.146); catalogued as COSV52750384; called by muse, mutect2
- CHD2 | c.4964C>T p.P1655L | Missense Mutation (SNP) | VAF 127/386 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1371556114, COSV67712848; called by muse, mutect2, varscan2
- CHD4 | c.1688G>A p.R563Q (on ENST00000357008 / NM_001363606.2; = p.R576Q on NM_001273.5) | Missense Mutation (SNP) | VAF 184/363 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs745467712, COSV58899454; called by muse, mutect2, varscan2
- CTSO | c.919A>C p.S307R | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs145957354; called by muse, mutect2, varscan2
- CYLC1 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 250/251 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV61411679, COSV61416457; called by muse, mutect2, varscan2
- CYP2R1 | c.1242G>C p.W414C | Missense Mutation (SNP) | VAF 152/254 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584961; called by muse, mutect2, varscan2
- DDI1 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 615/740 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs778814876, COSV56374301; called by muse, mutect2, varscan2
- DMAP1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs141586055; called by muse, mutect2, varscan2
- DNAH10 | c.10013G>T p.R3338M (on ENST00000409039; = p.R3277M on NM_207437.3) | Missense Mutation (SNP) | VAF 146/415 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs761688047; called by muse, mutect2, varscan2
- DNAI2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 92/543 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779268065; called by muse, mutect2, varscan2
- DNMT3B | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 82/548 reads (15%) | catalogued as COSV52415230; called by muse, mutect2, varscan2
- ENTPD8 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 131/400 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs778943060, COSV58162555, COSV58163354; called by muse, mutect2, varscan2
- EPB41L3 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535892749, COSV59468132; called by muse, mutect2, varscan2
- EXTL3 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.889); catalogued as rs368469541, COSV99593941; called by muse, mutect2, varscan2
- F7 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 194/663 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as rs774077974; called by muse, mutect2, varscan2
- FMOD | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 112/408 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs200131296, COSV61610121; called by muse, mutect2, varscan2
- FOXI3 | c.355T>G p.S119A | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1205992982; called by mutect2, varscan2
- FRS3 | c.851A>G p.K284R | Missense Mutation (SNP) | VAF 156/748 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1476051213; called by muse, mutect2, varscan2
- GALR2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 331/757 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs766251513; called by muse, mutect2, varscan2
- GAP43 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.005); catalogued as rs774808326, COSV59344326; called by muse, mutect2, varscan2
- GBX1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 227/650 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.114); catalogued as rs929453570; called by muse, mutect2, varscan2
- GDF6 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 96/420 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54627856; called by muse, varscan2
- GOLGA6L2 | c.2135C>T p.T712M | Missense Mutation (SNP) | VAF 108/832 reads (13%) | SIFT deleterious, low confidence (0); catalogued as rs368659484, COSV61474739; called by muse, varscan2
- GPLD1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 141/374 reads (38%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as rs143246933; called by muse, mutect2, varscan2
- HTR1E | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 135/422 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs778362756, COSV59506609; called by muse, mutect2, varscan2
- ITGB2 | c.1832G>A p.R611H (on ENST00000302347; = p.R587H on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 269/598 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs772406915; called by muse, mutect2, varscan2
- KCNC1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 398/612 reads (65%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs749447979, COSV56393492; called by muse, varscan2
- KCTD19 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV100431026; called by muse, mutect2, varscan2
- KIDINS220 | c.3865C>T p.R1289C | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.359); catalogued as rs781331572, COSV56751314; called by muse, mutect2, varscan2
- KNL1 | c.3281T>G p.L1094R (on ENST00000346991 / NM_170589.5; = p.L1068R on NM_144508.5) | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1221728857; called by muse, mutect2, varscan2
- KRTAP10-5 | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 191/746 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1445667534; called by muse, mutect2, varscan2
- LGI2 | c.198G>A p.L66= | Splice Region (SNP) | VAF 62/202 reads (31%) | catalogued as COSV66122762; called by muse, mutect2, varscan2
- LRP1B | c.8066G>T p.C2689F | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67196430, COSV67242164; called by muse, mutect2, varscan2
- LRRC53 | c.2513C>A p.S838* | Nonsense Mutation (SNP) | VAF 92/339 reads (27%) | catalogued as rs778420807; called by muse, mutect2, varscan2
- LSM8 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 138/320 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0.013); catalogued as rs1178538195; called by muse, mutect2
- MAPT | c.895G>A p.V299I (on ENST00000262410 / NM_001377265.1; = p.V224I on NM_016835.4) | Missense Mutation (SNP) | VAF 580/1035 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1378923121, COSV52242838; called by muse, mutect2, varscan2
- MCUR1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756791116; called by muse, mutect2, varscan2
- MFSD12 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 103/424 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1293915494, COSV100281481; called by muse, mutect2, varscan2
- MGAM | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs782082021; called by muse, mutect2, varscan2
- MMP23B | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 326/504 reads (65%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as rs564776074; called by muse, varscan2
- MPDZ | c.1197dup p.L400Ifs*18 | Frame Shift Ins (INS) | VAF 46/112 reads (41%) | catalogued as rs1554704601; called by mutect2, pindel, varscan2
- MYH7B | c.5359G>A p.G1787R | Missense Mutation (SNP) | VAF 78/602 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs754843230; called by muse, varscan2
- MYO15A | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 128/287 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775739005, COSV52760353; called by muse, mutect2, varscan2
- NFKBIB | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 236/548 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as rs1191667685; called by muse, varscan2
- NOS2 | c.2885G>A p.R962Q | Missense Mutation (SNP) | VAF 76/470 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as rs747552158; called by muse, mutect2, varscan2
- NRG3 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs374849923, COSV64570610; called by muse, mutect2, varscan2
- NT5C1A | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773014170; called by muse, mutect2, varscan2
- NUCB1 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 310/312 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as rs773762425; called by muse, mutect2, varscan2
- NUDT17 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 130/468 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.498); catalogued as rs782734985; called by muse, mutect2, varscan2
- OR51S1 | c.667T>G p.F223V | Missense Mutation (SNP) | VAF 120/351 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV59058314; called by muse, mutect2, varscan2
- OR6C3 | c.103A>C p.S35R | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as COSV65570938; called by muse, mutect2, varscan2
- PAPLN | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 103/549 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367760649, COSV99388985; called by muse, mutect2
- PCDHA9 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 133/373 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.671); catalogued as rs781938312, COSV65323085; called by muse, mutect2, varscan2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2
- PGBD4 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 132/499 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs746331134; called by muse, mutect2, varscan2
- PIWIL1 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 254/417 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99806692; called by muse, mutect2, varscan2
- POM121L2 | c.1769C>T p.T590M | Missense Mutation (SNP) | VAF 178/481 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs16897529; called by muse, mutect2, varscan2
- PPP1R32 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 416/558 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs746374003, COSV58543998; called by muse, mutect2, varscan2
- PRRC2C | c.3625C>T p.R1209C (on ENST00000367742; = p.R1207C on NM_015172.4) | Missense Mutation (SNP) | VAF 115/355 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769267279, COSV58904732; called by muse, mutect2, varscan2
- PRXL2B | c.641C>T p.S214F (on ENST00000444521; = p.S166F on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 145/431 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56518228; called by muse, mutect2, varscan2
- PTPRC | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs776036789, COSV61413887; called by muse, mutect2, varscan2
- PWWP2B | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 277/598 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs751968534, COSV59448823; called by muse, mutect2, varscan2
- RASIP1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 317/648 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1377791817; called by muse, mutect2, varscan2
- REG3G | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 127/267 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV55449177; called by muse, mutect2, varscan2
- RIMBP2 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55466023, COSV55470989, COSV55480263; called by muse, mutect2, varscan2
- ROS1 | c.6805C>T p.R2269* | Nonsense Mutation (SNP) | VAF 102/277 reads (37%) | catalogued as rs202153378, COSV100877678, COSV63851197; called by muse, mutect2, varscan2
- RTP2 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 210/591 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs754331122, COSV64079023; called by muse, mutect2, varscan2
- SLC13A3 | c.608+1G>A p.X203_splice | Splice Site (SNP) | VAF 242/474 reads (51%) | catalogued as rs773149390; called by muse, mutect2, varscan2
- SLC26A4 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 182/274 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775610413, COSV99706655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC29A2 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 116/458 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237016; called by muse, mutect2, varscan2
- SLC35E4 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 158/262 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs766424419, COSV55898627; called by muse, mutect2, varscan2
- SNTG1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV52451225; called by muse, mutect2, varscan2
- SSC5D | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 220/478 reads (46%) | catalogued as rs185224189; called by muse, varscan2
- STAB2 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 105/333 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV66343716; called by muse, mutect2, varscan2
- SYNE1 | c.1774G>A p.A592T (on ENST00000367255 / NM_182961.4; = p.A599T on NM_033071.3) | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs747150703; called by muse, mutect2, varscan2
- TBC1D3F | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 133/509 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1325744440; called by muse, mutect2, varscan2
- TBC1D4 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 107/368 reads (29%) | catalogued as rs771771231, COSV66487443; called by muse, mutect2, varscan2
- TET2 | c.2386G>T p.E796* | Nonsense Mutation (SNP) | VAF 261/262 reads (100%) | catalogued as COSV54409904; called by muse, mutect2, varscan2
- TEX11 | c.990T>A p.H330Q (on ENST00000344304; = p.H315Q on NM_031276.3) | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV60227392; called by muse, mutect2, varscan2
- THSD4 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs756810656, COSV99965719; called by muse, mutect2, varscan2
- TNRC6A | c.5639G>A p.S1880N | Missense Mutation (SNP) | VAF 301/723 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1173172606; called by muse, mutect2, varscan2
- TNS3 | c.1771C>A p.R591S | Missense Mutation (SNP) | VAF 167/535 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.389); catalogued as COSV60797139; called by muse, mutect2, varscan2
- TOE1 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 203/303 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377665053; called by muse, mutect2, varscan2
- TOPAZ1 | c.4286G>C p.G1429A | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59066531; called by muse, mutect2, varscan2
- TRPV5 | c.2189G>T p.*730Lext*29 | Nonstop Mutation (SNP) | VAF 35/318 reads (11%) | catalogued as rs571420259, COSV99520440; called by muse, mutect2, varscan2
- USP13 | c.1844G>A p.R615Q | Missense Mutation (SNP) | VAF 213/405 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs374433568, COSV55867131; called by muse, mutect2, varscan2
- ZFHX3 | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.186); catalogued as rs765294332, COSV51711517, COSV51731842; called by muse, mutect2, varscan2
- ZNF230 | c.1064A>G p.Q355R | Missense Mutation (SNP) | VAF 64/301 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as rs1568498183; called by muse, mutect2, varscan2
- ZNF507 | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 124/282 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs201200260, COSV61329697; called by muse, mutect2, varscan2
- ABCG8 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 247/506 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- AC092835.1 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 80/375 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACSM3 | c.1393A>T p.M465L | Missense Mutation (SNP) | VAF 81/312 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ADAM12 | c.592T>C p.S198P | Missense Mutation (SNP) | VAF 91/338 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AFTPH | c.1583T>G p.L528R | Missense Mutation (SNP) | VAF 92/356 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AHNAK | c.1690A>T p.T564S | Missense Mutation (SNP) | VAF 91/405 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- AKAP12 | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKNAD1 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALK | c.2913A>G p.K971= | Splice Region (SNP) | VAF 309/309 reads (100%) | called by muse, mutect2, varscan2
- AR | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 394/396 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ARHGAP27 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 560/1048 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATG7 | c.989A>T p.E330V | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- BHLHE40 | c.280del p.A94Qfs*8 | Frame Shift Del (DEL) | VAF 51/197 reads (26%) | called by mutect2, pindel, varscan2
- BSN | c.9016G>A p.G3006S | Missense Mutation (SNP) | VAF 322/475 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CABLES1 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 401/609 reads (66%) | called by muse, mutect2, varscan2
- CACNA1A | c.1949A>C p.N650T | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CACNA1F | c.3349_3351del p.F1117del | In Frame Del (DEL) | VAF 219/227 reads (96%) | called by pindel, varscan2
- CALCRL | c.1138G>C p.V380L | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCSER2 | c.2139A>T p.K713N | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD180 | c.1765T>A p.L589I | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDCP1 | c.805T>G p.F269V | Missense Mutation (SNP) | VAF 98/313 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CLDN24 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 107/585 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNTNAP5 | c.1887G>C p.W629C | Missense Mutation (SNP) | VAF 131/273 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPNE2 | c.257A>G p.E86G | Missense Mutation (SNP) | VAF 109/363 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DDIAS | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 597/666 reads (90%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNAH8 | c.10640A>C p.K3547T | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTX2 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 165/548 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DUSP5 | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 119/409 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- DYRK2 | c.511G>T p.E171* (on ENST00000344096 / NM_006482.3; = p.E98* on NM_003583.4) | Nonsense Mutation (SNP) | VAF 90/246 reads (37%) | called by muse, mutect2, varscan2
- EDRF1 | c.3650A>C p.N1217T (on ENST00000356792 / NM_001202438.2; = p.N1183T on NM_015608.2) | Missense Mutation (SNP) | VAF 93/429 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EIF5 | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ELMOD3 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- EPHA4 | c.385T>C p.S129P | Missense Mutation (SNP) | VAF 90/433 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS8L1 | c.1198T>C p.S400P (on ENST00000201647 / NM_133180.3; = p.S273P on NM_017729.3) | Missense Mutation (SNP) | VAF 101/518 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- FAHD2A | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 384/391 reads (98%) | called by muse, mutect2, varscan2
- FAM171B | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 289/289 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- FAM76B | c.590A>C p.E197A | Missense Mutation (SNP) | VAF 130/216 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAT2 | c.1503A>C p.K501N | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXO11 | c.860T>C p.L287P (on ENST00000403359 / NM_001190274.2; = p.L203P on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- FCHSD1 | c.1250A>C p.E417A | Missense Mutation (SNP) | VAF 170/581 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FES | c.1331dup p.L445Afs*13 | Frame Shift Ins (INS) | VAF 76/271 reads (28%) | called by mutect2, pindel, varscan2
- FLNC | c.1469G>C p.R490P | Missense Mutation (SNP) | VAF 239/342 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FLT1 | c.131A>C p.Q44P | Missense Mutation (SNP) | VAF 104/331 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FUBP3 | c.718T>C p.F240L | Missense Mutation (SNP) | VAF 68/247 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GABRG3 | c.781T>A p.Y261N | Missense Mutation (SNP) | VAF 108/461 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GEMIN5 | c.2363A>G p.E788G | Missense Mutation (SNP) | VAF 100/316 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- GSTM1 | c.7A>T p.M3L | Missense Mutation (SNP) | VAF 270/270 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, varscan2
- HELLS | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HERC1 | c.4905A>C p.E1635D | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HERC5 | c.2944A>T p.S982C | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HIPK1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 229/355 reads (65%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HIPK3 | c.1717A>G p.S573G | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- HLX | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 183/576 reads (32%) | called by muse, mutect2, varscan2
- IGF2R | c.4909T>A p.F1637I | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- INVS | c.2053T>C p.S685P | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- IQCN | c.2294T>G p.L765R | Missense Mutation (SNP) | VAF 115/436 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- IQGAP3 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 156/476 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- ITGAL | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 82/373 reads (22%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- KCNA5 | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 368/722 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KDM6A | c.1843_1856del p.L615* | Frame Shift Del (DEL) | VAF 123/128 reads (96%) | called by mutect2, pindel, varscan2
- KEL | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 133/472 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KHDRBS3 | c.511T>G p.L171V | Missense Mutation (SNP) | VAF 88/314 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- KLF18 | c.637A>C p.M213L | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KMT2B | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 127/388 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.043); called by mutect2, varscan2
- KMT2D | c.13247A>T p.K4416M | Missense Mutation (SNP) | VAF 150/410 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KRT6B | c.581A>C p.K194T | Missense Mutation (SNP) | VAF 151/603 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KRTAP5-8 | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 194/3386 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- LAP3 | c.626A>G p.E209G | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- LCT | c.4370T>A p.L1457H | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LILRA1 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 91/405 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LIMD2 | c.224G>A p.S75N | Missense Mutation (SNP) | VAF 196/438 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LONP1 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 173/344 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- M1AP | c.1348T>A p.S450T | Missense Mutation (SNP) | VAF 141/513 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- MAP4 | c.222A>G p.E74= | Splice Region (SNP) | VAF 107/163 reads (66%) | called by muse, mutect2, varscan2
- MDN1 | c.4147G>A p.G1383S | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MGAM | c.3722A>G p.Y1241C | Missense Mutation (SNP) | VAF 80/370 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLH3 | c.3815G>T p.R1272M (on ENST00000355774 / NM_001040108.2; = p.R1248M on NM_014381.3) | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MLH3 | c.3814A>G p.R1272G (on ENST00000355774 / NM_001040108.2; = p.R1248G on NM_014381.3) | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MOV10L1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 92/307 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH7 | c.2433dup p.L812Afs*75 | Frame Shift Ins (INS) | VAF 83/416 reads (20%) | called by mutect2, pindel, varscan2
- MYO5C | c.3219G>T p.E1073D | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NF1 | c.5206G>A p.D1736N (on ENST00000358273 / NM_001042492.3; = p.D1715N on NM_000267.3) | Missense Mutation (SNP) | VAF 93/581 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- NKX2-4 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 176/556 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OOEP | c.100del p.I34Ffs*13 | Frame Shift Del (DEL) | VAF 106/385 reads (28%) | called by mutect2, pindel, varscan2
- OPLAH | c.3091A>T p.T1031S | Missense Mutation (SNP) | VAF 157/677 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- OTOG | c.7298A>G p.K2433R | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- P2RX3 | c.960dup p.T321Hfs*20 | Frame Shift Ins (INS) | VAF 461/653 reads (71%) | called by mutect2, pindel, varscan2
- PACS1 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 724/851 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PAPPA | c.2235T>G p.G745= | Splice Region (SNP) | VAF 63/202 reads (31%) | called by muse, mutect2, varscan2
- PATL1 | c.1912A>G p.S638G | Missense Mutation (SNP) | VAF 82/331 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHACTR1 | c.335A>C p.K112T | Missense Mutation (SNP) | VAF 164/496 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLA2G15 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 132/439 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PLEC | c.1829G>A p.R610K (on ENST00000322810 / NM_201380.4; = p.R500K on NM_000445.5) | Missense Mutation (SNP) | VAF 108/435 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PNPLA7 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 296/423 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PODXL | c.1175A>C p.Q392P (on ENST00000378555 / NM_001018111.3; = p.Q360P on NM_005397.4) | Missense Mutation (SNP) | VAF 119/384 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- POLR2D | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARGC1B | c.1018T>G p.F340V | Missense Mutation (SNP) | VAF 170/539 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP4R3C | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 170/170 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PRDM13 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, varscan2
- PROX1 | c.2093C>T p.A698V | Missense Mutation (SNP) | VAF 111/296 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PTGER2 | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRE | c.1167A>T p.Q389H | Missense Mutation (SNP) | VAF 76/320 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PTPRT | c.4168G>A p.A1390T | Missense Mutation (SNP) | VAF 84/676 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RECQL4 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 113/383 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- REV3L | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 122/199 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RHOF | c.234A>C p.E78D | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RIMBP3 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 186/1242 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RNF123 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.388); called by muse, mutect2
- RNF31 | c.2555A>G p.D852G | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RPL10L | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 221/559 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RUSC2 | c.4504A>C p.T1502P | Missense Mutation (SNP) | VAF 118/421 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SCGB1D2 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 119/458 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SDR9C7 | c.875A>C p.K292T | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SETD3 | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SHANK1 | c.3128C>T p.P1043L | Missense Mutation (SNP) | VAF 226/467 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SKIV2L | c.2993G>A p.G998D | Missense Mutation (SNP) | VAF 296/756 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLC25A33 | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SLC27A5 | c.687A>T p.P229= | Splice Region (SNP) | VAF 69/315 reads (22%) | called by muse, mutect2, varscan2
- SLITRK5 | c.2481C>G p.H827Q | Missense Mutation (SNP) | VAF 190/578 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- SOST | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 462/1030 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SPATA31D1 | c.4172T>G p.V1391G | Missense Mutation (SNP) | VAF 117/341 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPTBN2 | c.1298A>G p.K433R | Missense Mutation (SNP) | VAF 158/1952 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SREK1 | c.983A>G p.D328G | Missense Mutation (SNP) | VAF 111/210 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRM5 | c.802A>C p.S268R | Missense Mutation (SNP) | VAF 109/427 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- ST8SIA4 | c.292G>T p.V98F | Missense Mutation (SNP) | VAF 85/165 reads (52%) | PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- STOX1 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SUDS3 | c.905C>G p.T302R | Missense Mutation (SNP) | VAF 159/273 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SYT1 | c.1262A>C p.K421T | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TARS3 | c.2057A>T p.N686I | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TEP1 | c.6559T>C p.S2187P | Missense Mutation (SNP) | VAF 124/616 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TESPA1 | c.1549G>A p.A517T (on ENST00000316577 / NM_001098815.3; = p.A379T on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 209/314 reads (67%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TET3 | c.3470A>T p.K1157M | Missense Mutation (SNP) | VAF 127/513 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TMEM232 | c.1910G>A p.R637K | Missense Mutation (SNP) | VAF 154/154 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TMEM87A | c.1532A>C p.N511T | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRAPPC11 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 66/361 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, varscan2
- TRPC4 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 93/197 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TSSK6 | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 239/481 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- TYW1 | c.1910T>C p.L637P | Missense Mutation (SNP) | VAF 117/282 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- UBA5 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 185/251 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- UTP14C | c.870_874del p.M290Ifs*6 | Frame Shift Del (DEL) | VAF 80/283 reads (28%) | called by mutect2, pindel, varscan2
- UVSSA | c.1826A>G p.E609G | Missense Mutation (SNP) | VAF 114/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- VPS13C | c.2543C>T p.S848F (on ENST00000644861 / NM_020821.3; = p.S805F on NM_017684.5) | Missense Mutation (SNP) | VAF 133/195 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- VWF | c.2290A>G p.S764G | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XIRP2 | c.491A>G p.Q164R (on ENST00000628543; = p.Q339R on NM_152381.6) | Missense Mutation (SNP) | VAF 239/239 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- Z83844.2 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZC3H4 | c.1478A>C p.E493A | Missense Mutation (SNP) | VAF 74/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF415 | c.51A>C p.Q17H | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ZNF773 | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF831 | c.2335G>C p.V779L | Missense Mutation (SNP) | VAF 146/982 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.026); called by muse, mutect2
- ZNF84 | c.1498T>G p.L500V | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ABCC8 | c.3996G>A p.S1332= | Silent (SNP) | VAF 174/276 reads (63%) | catalogued as rs746146690; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAM12 | c.591C>A p.P197= | Silent (SNP) | VAF 92/343 reads (27%) | catalogued as COSV64108596; called by muse, mutect2, varscan2
- ADAMTS16 | c.3435C>T p.G1145= | Silent (SNP) | VAF 577/578 reads (100%) | catalogued as rs749675084, COSV57001535; called by muse, mutect2, varscan2
- ADGRB1 | c.2811C>T p.A937= | Silent (SNP) | VAF 102/404 reads (25%) | catalogued as rs1294146727; called by muse, varscan2
- AKR7A2 | c.855C>T p.G285= | Silent (SNP) | VAF 224/376 reads (60%) | catalogued as rs190445327; called by muse, mutect2, varscan2
- ANKRD33B | c.1464G>T p.A488= | Silent (SNP) | VAF 70/284 reads (25%) | called by muse, mutect2, varscan2
- APCDD1 | c.1026C>T p.Y342= | Silent (SNP) | VAF 128/399 reads (32%) | catalogued as rs186987345; called by muse, mutect2, varscan2
- ASPSCR1 | c.177C>T p.L59= | Silent (SNP) | VAF 79/463 reads (17%) | catalogued as rs373929219; called by muse, mutect2, varscan2
- ATP2B4 | c.3006G>A p.L1002= | Silent (SNP) | VAF 79/280 reads (28%) | called by muse, mutect2, varscan2
- BAHCC1 | c.84G>A p.A28= | Silent (SNP) | VAF 426/728 reads (59%) | called by muse, mutect2, varscan2
- C7 | c.1035C>T p.V345= | Silent (SNP) | VAF 70/399 reads (18%) | catalogued as rs377251576; called by muse, mutect2, varscan2
- CACNA1C | c.720C>T p.R240= | Silent (SNP) | VAF 231/462 reads (50%) | catalogued as rs527755968, COSV100216019; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCHCR1 | c.1830T>A p.T610= | Silent (SNP) | VAF 132/638 reads (21%) | called by muse, mutect2, varscan2
- CITED2 | c.267C>T p.P89= | Silent (SNP) | VAF 152/494 reads (31%) | called by muse, mutect2, varscan2
- CLHC1 | c.1044C>T p.L348= | Silent (SNP) | VAF 236/236 reads (100%) | called by muse, mutect2, varscan2
- CRACDL | c.1950G>A p.P650= | Silent (SNP) | VAF 168/675 reads (25%) | catalogued as rs1010904754; called by muse, mutect2, varscan2
- CRYBG3 | c.4566A>G p.V1522= | Silent (SNP) | VAF 89/352 reads (25%) | catalogued as rs1245820799; called by muse, mutect2, varscan2
- CTDP1 | c.2187G>A p.R729= | Silent (SNP) | VAF 150/444 reads (34%) | catalogued as rs1420531995; called by muse, mutect2, varscan2
- DGKK | c.630G>A p.S210= | Silent (SNP) | VAF 280/282 reads (99%) | catalogued as rs1557234338, COSV101052853; called by muse, mutect2, varscan2
- ECEL1 | c.75G>A p.A25= | Silent (SNP) | VAF 522/524 reads (100%) | catalogued as rs985763887, COSV58811218; called by mutect2, varscan2
- ESR1 | c.240C>T p.Y80= | Silent (SNP) | VAF 172/579 reads (30%) | catalogued as COSV52786512; called by muse, mutect2, varscan2
- FAM171A2 | c.1083C>T p.D361= | Silent (SNP) | VAF 318/571 reads (56%) | catalogued as COSV50007818, COSV50009118; called by muse, varscan2
- FAM184A | c.1600C>T p.L534= | Silent (SNP) | VAF 49/169 reads (29%) | called by muse, mutect2, varscan2
- FBLL1 | c.360G>A p.T120= | Silent (SNP) | VAF 304/489 reads (62%) | called by muse, varscan2
- GPR78 | c.519C>T p.T173= | Silent (SNP) | VAF 329/507 reads (65%) | catalogued as rs112091210, COSV66762815; called by muse, mutect2, varscan2
- GSTM2 | c.102G>A p.T34= | Silent (SNP) | VAF 128/231 reads (55%) | catalogued as rs370258500, COSV53983510, COSV99598089; called by muse, mutect2, varscan2
- GUCA2B | c.291C>T p.N97= | Silent (SNP) | VAF 209/313 reads (67%) | catalogued as rs373014813; called by muse, mutect2, varscan2
- HERC1 | c.8424C>T p.S2808= | Silent (SNP) | VAF 366/487 reads (75%) | catalogued as rs1179061887; called by muse, mutect2, varscan2
- HGD | c.477G>A p.Q159= | Silent (SNP) | VAF 64/317 reads (20%) | catalogued as rs1351109217; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSPA12A | c.1911C>T p.P637= | Silent (SNP) | VAF 136/420 reads (32%) | catalogued as rs781805969, COSV65022456; called by muse, mutect2, varscan2
- KMT2C | c.13767T>C p.T4589= | Silent (SNP) | VAF 99/325 reads (30%) | called by muse, mutect2, varscan2
- KRT6C | c.783A>G p.T261= | Silent (SNP) | VAF 104/305 reads (34%) | called by muse, mutect2
- MAPK9 | c.879A>G p.Q293= | Silent (SNP) | VAF 63/201 reads (31%) | called by muse, mutect2, varscan2
- MAT1A | c.1149C>T p.S383= | Silent (SNP) | VAF 81/265 reads (31%) | catalogued as rs777184287, COSV64745121; called by muse, varscan2
- MDGA2 | c.390T>G p.T130= | Silent (SNP) | VAF 116/269 reads (43%) | called by muse, mutect2, varscan2
- MET | c.3348T>C p.T1116= | Silent (SNP) | VAF 63/2092 reads (3%) | called by muse, mutect2
- MRGPRE | c.876C>T p.D292= | Silent (SNP) | VAF 404/608 reads (66%) | catalogued as rs373696773; called by muse, mutect2, varscan2
- MTMR4 | c.109C>T p.L37= | Silent (SNP) | VAF 253/455 reads (56%) | called by muse, mutect2, varscan2
- MUC12 | c.234G>A p.E78= | Silent (SNP) | VAF 371/669 reads (55%) | catalogued as rs1433563406; called by muse, mutect2, varscan2
- MYO18B | c.2838T>C p.S946= | Silent (SNP) | VAF 92/286 reads (32%) | catalogued as rs746453019; called by muse, mutect2, varscan2
- MYO19 | c.1239G>A p.L413= | Silent (SNP) | VAF 175/316 reads (55%) | called by muse, mutect2, varscan2
- MYO5B | c.3492A>G p.Q1164= | Silent (SNP) | VAF 100/303 reads (33%) | called by muse, mutect2, varscan2
- MZF1 | c.402A>G p.T134= | Silent (SNP) | VAF 64/278 reads (23%) | called by muse, mutect2, varscan2
- NEU2 | c.747C>T p.T249= | Silent (SNP) | VAF 574/574 reads (100%) | called by muse, mutect2, varscan2
- NKX1-1 | c.1008C>T p.T336= | Silent (SNP) | VAF 170/459 reads (37%) | catalogued as rs753203581, COSV70026213; called by muse, mutect2, varscan2
- NKX6-1 | c.177G>A p.S59= | Silent (SNP) | VAF 151/479 reads (32%) | catalogued as COSV55685494, COSV55685832; called by muse, mutect2, varscan2
- NOTCH1 | c.2475G>A p.T825= | Silent (SNP) | VAF 106/358 reads (30%) | catalogued as rs766045141; called by muse, mutect2, varscan2
- NPIPB15 | c.622A>C p.R208= | Silent (SNP) | VAF 134/1242 reads (11%) | called by muse, mutect2, varscan2
- NPY1R | c.384T>C p.I128= | Silent (SNP) | VAF 66/449 reads (15%) | catalogued as COSV56713224, COSV99648810; called by muse, mutect2, varscan2
- NUTM2F | c.828C>T p.Y276= | Silent (SNP) | VAF 87/323 reads (27%) | catalogued as rs548549159, COSV53555398; called by muse, mutect2, varscan2
- OLIG2 | c.69G>A p.P23= | Silent (SNP) | VAF 127/552 reads (23%) | catalogued as rs775046241, COSV60972703; called by muse, mutect2, varscan2
- OR10AC1 | c.819G>A p.A273= | Silent (SNP) | VAF 180/537 reads (34%) | catalogued as rs1268618171; called by muse, mutect2, varscan2
- OR52K2 | c.810T>C p.A270= | Silent (SNP) | VAF 103/304 reads (34%) | called by muse, mutect2, varscan2
- PCDHA5 | c.858C>T p.D286= | Silent (SNP) | VAF 103/169 reads (61%) | catalogued as rs143650923, COSV65356552; called by muse, mutect2, varscan2
- PIGG | c.723C>T p.S241= | Silent (SNP) | VAF 72/273 reads (26%) | catalogued as rs782415035, COSV99573853; called by muse, mutect2, varscan2
- PODXL2 | c.459G>A p.E153= | Silent (SNP) | VAF 108/442 reads (24%) | called by muse, mutect2, varscan2
- PPP1R18 | c.1455A>G p.P485= | Silent (SNP) | VAF 180/854 reads (21%) | catalogued as rs1448077157; called by muse, varscan2
- PRAMEF26 | c.990G>T p.L330= | Silent (SNP) | VAF 82/632 reads (13%) | called by muse, mutect2, varscan2
- PRDM9 | c.1083C>T p.Y361= | Silent (SNP) | VAF 299/432 reads (69%) | catalogued as rs777790549, COSV57014303; called by muse, mutect2, varscan2
- PRR36 | c.183A>T p.R61= | Silent (SNP) | VAF 176/694 reads (25%) | called by muse, mutect2, varscan2
- PSG8 | c.522G>A p.P174= | Silent (SNP) | VAF 59/313 reads (19%) | catalogued as rs187064013; called by muse, mutect2, varscan2
- SCARA3 | c.919T>C p.L307= | Silent (SNP) | VAF 109/439 reads (25%) | called by muse, mutect2, varscan2
- SHANK2 | c.5037T>C p.T1679= | Silent (SNP) | VAF 150/1887 reads (8%) | called by muse, mutect2
- SHC1 | c.1434C>T p.S478= (on ENST00000368445 / NM_183001.5; = p.S369= on NM_003029.5) | Silent (SNP) | VAF 109/566 reads (19%) | catalogued as rs746443463; called by muse, mutect2, varscan2
- SLC22A25 | c.27A>G p.Q9= | Silent (SNP) | VAF 58/386 reads (15%) | catalogued as COSV60599307; called by muse, mutect2, varscan2
- SLC33A1 | c.846C>T p.N282= | Silent (SNP) | VAF 40/256 reads (16%) | catalogued as rs1341440565, COSV63946688; called by muse, mutect2, varscan2
- SLIT3 | c.3009C>T p.N1003= | Silent (SNP) | VAF 380/381 reads (100%) | catalogued as rs564660437; called by muse, mutect2, varscan2
- SMG8 | c.2898T>A p.P966= | Silent (SNP) | VAF 88/505 reads (17%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.672G>A p.A224= | Silent (SNP) | VAF 124/551 reads (23%) | catalogued as rs1235331966; called by muse, mutect2, varscan2
- STAB2 | c.2274C>T p.L758= | Silent (SNP) | VAF 85/284 reads (30%) | catalogued as rs760239562; called by muse, mutect2, varscan2
- TBC1D12 | c.1434A>C p.R478= | Silent (SNP) | VAF 61/209 reads (29%) | called by muse, mutect2, varscan2
- TEX2 | c.1953T>G p.T651= | Silent (SNP) | VAF 67/505 reads (13%) | called by muse, mutect2, varscan2
- TG | c.5202C>T p.C1734= | Silent (SNP) | VAF 160/346 reads (46%) | catalogued as COSV55071898; called by muse, mutect2, varscan2
- TLCD1 | c.300G>A p.V100= | Silent (SNP) | VAF 166/415 reads (40%) | called by muse, mutect2, varscan2
- TMCC1 | c.969G>A p.R323= | Silent (SNP) | VAF 308/425 reads (72%) | catalogued as COSV61443440; called by muse, mutect2, varscan2
- TMEM266 | c.390C>T p.S130= | Silent (SNP) | VAF 204/302 reads (68%) | catalogued as rs761400106, COSV66379626; called by muse, mutect2, varscan2
- TMEM68 | c.627T>G p.T209= | Silent (SNP) | VAF 92/313 reads (29%) | catalogued as rs1221486018; called by muse, mutect2, varscan2
- TRMT5 | c.1059C>T p.N353= | Silent (SNP) | VAF 224/484 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.43926C>T p.T14642= (on ENST00000591111; = p.T7218= on NM_003319.4) | Silent (SNP) | VAF 157/339 reads (46%) | catalogued as rs768147224, COSV100617463, COSV60291972; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBB2B | c.1071G>A p.P357= | Silent (SNP) | VAF 86/596 reads (14%) | called by muse, mutect2, varscan2
- VSTM2A | c.240C>T p.G80= | Silent (SNP) | VAF 240/586 reads (41%) | called by muse, mutect2, varscan2
- WAPL | c.1182A>G p.E394= | Silent (SNP) | VAF 75/268 reads (28%) | catalogued as COSV53941092; called by muse, mutect2, varscan2
- WDCP | c.1905T>G p.T635= | Silent (SNP) | VAF 75/331 reads (23%) | catalogued as COSV54593145; called by muse, mutect2, varscan2
- WNK3 | c.3363C>T p.L1121= | Silent (SNP) | VAF 216/216 reads (100%) | catalogued as COSV63612360, COSV63616355; called by muse, mutect2, varscan2
- WRNIP1 | c.1227T>G p.P409= | Silent (SNP) | VAF 116/329 reads (35%) | called by muse, mutect2, varscan2
- ZFPM1 | c.1593C>T p.F531= | Silent (SNP) | VAF 185/644 reads (29%) | catalogued as COSV60323249; called by muse, varscan2
- ZNF606 | c.1524A>G p.G508= | Silent (SNP) | VAF 101/365 reads (28%) | called by muse, mutect2, varscan2
- ZNF780B | c.660T>A p.T220= | Silent (SNP) | VAF 93/394 reads (24%) | called by muse, mutect2, varscan2
- ZNF883 | c.774T>C p.T258= | Silent (SNP) | VAF 99/402 reads (25%) | catalogued as COSV71309277; called by muse, mutect2, varscan2
- ADGRA1 | c.4-1256A>C | Intron (SNP) | VAF 107/484 reads (22%) | catalogued as COSV66931135; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851675 G>T | 3'Flank (SNP) | VAF 108/218 reads (50%) | called by muse, mutect2, varscan2
- ARMC5 | chr16:31458463 A>G | 5'Flank (SNP) | VAF 26/736 reads (4%) | called by muse, mutect2
- ARMC5 | c.1864+248C>T | Intron (SNP) | VAF 250/674 reads (37%) | catalogued as rs549737362; called by muse, mutect2
- C4orf50 | chr4:5990630 C>T | 5'Flank (SNP) | VAF 121/414 reads (29%) | called by muse, mutect2, varscan2
- CNKSR2 | c.2693-7295A>G | Intron (SNP) | VAF 222/222 reads (100%) | called by muse, mutect2, varscan2
- CUL7 | c.-172C>T | 5'UTR (SNP) | VAF 172/974 reads (18%) | called by muse, mutect2, varscan2
- DCHS2 | n.6627T>A | RNA (SNP) | VAF 122/335 reads (36%) | called by muse, mutect2, varscan2
- DNMBP | c.2261-20978G>T | Intron (SNP) | VAF 170/269 reads (63%) | catalogued as rs754180642; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-34833T>G | Intron (SNP) | VAF 76/222 reads (34%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+4373G>A | Intron (SNP) | VAF 109/365 reads (30%) | called by muse, mutect2, varscan2
- KCNQ2 | c.*5864G>A | 3'UTR (SNP) | VAF 403/1380 reads (29%) | called by muse, mutect2, varscan2
- LY6E | chr8:143018110 C>G | 5'Flank (SNP) | VAF 58/1046 reads (6%) | called by muse, mutect2
- MAMLD1 | c.*2C>A | 3'UTR (SNP) | VAF 232/232 reads (100%) | catalogued as rs368568633, COSV53373626; called by muse, mutect2, varscan2
- MAP4 | c.1999+5529G>A | Intron (SNP) | VAF 155/256 reads (61%) | catalogued as rs747227454; called by muse, mutect2, varscan2
- MYCBP2 | c.8026+2887T>G | Intron (SNP) | VAF 60/230 reads (26%) | called by muse, mutect2, varscan2
- NPEPL1 | chr20:58691209 A>G | 5'Flank (SNP) | VAF 56/455 reads (12%) | called by muse, mutect2, varscan2
- SLC17A2 | c.*116A>T | 3'UTR (SNP) | VAF 85/475 reads (18%) | called by muse, mutect2, varscan2
- ST7 | c.865+35C>T | Intron (SNP) | VAF 3014/3313 reads (91%) | called by muse, mutect2, varscan2
- SYT9 | c.*1458C>T | 3'UTR (SNP) | VAF 69/273 reads (25%) | catalogued as rs141164216; called by muse, mutect2, varscan2
- TBC1D3F | c.*109G>A | 3'UTR (SNP) | VAF 65/720 reads (9%) | called by muse, mutect2, varscan2
- TLCD3B | c.540+68T>G | Intron (SNP) | VAF 172/795 reads (22%) | called by muse, mutect2, varscan2
- WNT7B | c.71+4519G>A | Intron (SNP) | VAF 73/231 reads (32%) | catalogued as rs975122893; called by muse, mutect2, varscan2
- ZNF175 | c.*243A>C | 3'UTR (SNP) | VAF 65/294 reads (22%) | called by muse, mutect2, varscan2
- ZNF222 | c.142+251C>A | Intron (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
